Somatic mutation profile of tumor specimen MP2PRT-PAVTCF-TMP1-A (aliquot MP2PRT-PAVTCF-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVTCF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,487 days).
Specimen MP2PRT-PAVTCF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6d0f391-6eb7-4cf8-a745-bac2010d78ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTCF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTCF-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c867de3-2955-42b7-bb63-a6853584753d

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNN2 | c.22G>A p.G8R (on ENST00000264773; = p.G220R on NM_021614.4) | Missense Mutation (SNP) | VAF 166/386 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs761300611, COSV53296218; called by muse, mutect2, varscan2
- UBE2I | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV57647059; called by muse, mutect2, varscan2
- AGL | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 106/307 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DST | c.1889A>T p.D630V (on ENST00000361203 / NM_001374722.1; = p.D304V on NM_001723.6) | Missense Mutation (SNP) | VAF 78/206 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV1-58 | c.348_349insAGACGGGG p.A117Rfs*? | Frame Shift Ins (INS) | VAF 12/29 reads (41%) | called by mutect2, pindel*
- IL3RA | c.432-19_437delinsCC p.X144_splice | Splice Site (DEL) | VAF 141/387 reads (36%) | called by pindel, varscan2*
- PABPC3 | c.1717G>C p.A573P | Missense Mutation (SNP) | VAF 40/439 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RIC8A | c.905T>G p.F302C | Missense Mutation (SNP) | VAF 142/360 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CDHR2 | c.990G>A p.G330= | Silent (SNP) | VAF 120/293 reads (41%) | called by muse, mutect2, varscan2
- HHIP | c.1006T>C p.L336= | Silent (SNP) | VAF 122/307 reads (40%) | catalogued as COSV99666337; called by muse, mutect2, varscan2
- SCARA5 | c.1305C>T p.G435= | Silent (SNP) | VAF 195/491 reads (40%) | catalogued as rs980021095; called by muse, mutect2, varscan2
- TBC1D19 | c.213G>A p.L71= | Silent (SNP) | VAF 62/173 reads (36%) | called by muse, mutect2, varscan2
- UPK3B | c.444G>A p.P148= (on ENST00000257632; = p.P93= on NM_001347684.2) | Silent (SNP) | VAF 44/585 reads (8%) | catalogued as rs199603935; called by muse, mutect2
